Gene-level copy-number profile of tumor specimen ALCH-B37W-TTP1-A from ALCHEMIST case ALCH-B37W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.0 years (28,507 days).
Specimen ALCH-B37W-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 58de8f3b-5763-4aa2-8821-86e8344a01a2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B37W-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,277 have no estimate.
https://portal.gdc.cancer.gov/files/02474640-387c-4e42-afb8-03bd88615717

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 3,778; copy number 2: 51,594; copy number 3: 2,184; copy number 4: 449; copy number 5: 142; copy number 6: 49; copy number 7: 13; copy number 8: 16; copy number 9: 13; copy number 10: 5; copy number 11: 6; copy number 12: 3; copy number 13: 1; copy number 14: 5; copy number 15: 6; copy number 17: 2; copy number 19: 2; copy number 20: 1; copy number 21: 3; copy number 22: 1; copy number 29: 1; copy number 30: 1; copy number 31: 1; copy number 37: 1; copy number 68: 2; copy number 172: 3.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,581,560–2,584,533, 1 gene: AL139246.3.
- chr2:87,565,828–87,566,764, 1 gene (within-gene range 0–5): PAFAH1B1P1.
- chr5:135,802,985–135,827,546, 2 genes: MIR5692C1, AC114296.1.
- chr5:176,006,145–176,007,387, 1 gene (within-gene range 0–1): OR1X1P.
- chr7:227,554–229,557, 1 gene (within-gene range 0–4): AC145676.1.
- chr8:143,366,631–143,368,548, 1 gene: RHPN1-AS1.
- chr8:144,049,079–144,051,522, 1 gene (within-gene range 0–11): SMPD5.
- chr9:61,642,383–61,642,494, 1 gene: Y_RNA.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.
- chr9:136,483,495–136,486,067, 1 gene (within-gene range 0–2): C9orf163.
- chr9:137,077,517–137,086,817, 2 genes: UAP1L1, MAN1B1-DT.
- chr9:137,168,758–137,172,056, 4 genes (within-gene range 0–6): LRRC26, AL929554.1, MIR3621, TMEM210.
- chr9:137,224,635–137,226,315, 1 gene: CYSRT1.
- chr10:125,473,686–125,473,932, 1 gene: RPS27P18.
- chr11:18,836,304–18,837,081, 1 gene: MRGPRX8P.
- chr11:18,910,436–18,911,396, 1 gene: MRGPRX5P.
- chr11:45,399,448–45,400,528, 1 gene (within-gene range 0–1): AC018716.1.
- chr12:5,226,196–5,244,199, 1 gene: LINC02443.
- chr12:52,565,782–52,573,843, 1 gene: KRT74.
- chr12:52,601,467–52,634,456, 3 genes (within-gene range 0–2): KRT73-AS1, KRT73, KRT128P.
- chr12:127,876,999–127,898,645, 2 genes: AC087894.1, LINC02393.
- chr12:128,399,978–128,404,814, 1 gene (within-gene range 0–1): AC023595.1.
- chr14:94,800,849–94,918,734, 2 genes: RPL15P2, AL121612.1.
- chr14:96,592,399–96,638,514, 2 genes: AL137786.1, RN7SKP108.
- chr14:97,786,565–97,789,256, 1 gene: AL355097.1.
- chr14:99,158,416–99,159,669, 1 gene: AL162151.1.
- chr14:101,064,495–101,077,910, 8 genes: MIR541, MIR409, MIR412, MIR369, MIR410, MIR656, MEG9, AL132709.7.
- chr14:101,133,730–101,151,988, 2 genes: AL355836.2, U3.
- chr14:106,257,762–106,258,223, 1 gene (within-gene range 0–2): IGHV3-22.
- chr14:106,309,417–106,318,236, 3 genes (within-gene range 0–2): IGHVIII-26-1, IGHVII-26-2, IGHV7-27.
- chr16:560,394–565,529, 1 gene: PRR35.
- chr16:1,286,351–1,299,166, 2 genes: TPSP2, AC120498.4.
- chr16:3,069,523–3,069,651, 1 gene (within-gene range 0–2): RNU1-125P.
- chr19:571,277–583,493, 1 gene (within-gene range 0–2): BSG.
- chr19:1,241,746–1,244,825, 1 gene: ATP5F1D.
- chr19:1,307,401–1,307,719, 1 gene (within-gene range 0–2): RPS15P9.
- chr19:56,066,684–56,127,466, 2 genes: LINC01864, AC024580.2.
- chr20:24,142,590–24,144,386, 1 gene: AL110503.1.
- chr20:57,168,753–57,282,998, 3 genes (within-gene range 0–3): BMP7, BMP7-AS1, AL122058.1.
- chr20:63,502,287–63,505,111, 1 gene: AL121829.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 277 genes in 106 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–133,723, 4 genes, copy number 6–8 (within-gene range 4–8): OR4G4P, OR4G11P, OR4F5, AL627309.1.
- chr1:131,025–195,411, 10 genes, copy number 6: CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr1:778,747–810,065, 2 genes, copy number 5 (within-gene range 4–5): LINC01409, AL669831.6.
- chr1:860,226–877,234, 2 genes, copy number 5: AL669831.7, AL669831.5.
- chr1:1,169,357–1,179,555, 2 genes, copy number 9 (within-gene range 1–9): AL390719.2, TTLL10-AS1.
- chr1:1,203,508–1,214,153, 2 genes, copy number 15–37: TNFRSF18, TNFRSF4.
- chr1:1,242,446–1,251,334, 2 genes, copy number 7–17: C1QTNF12, AL162741.1.
- chr1:147,172,744–147,295,734, 5 genes, copy number 5 (within-gene range 3–5): PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15.
- chr1:151,008,420–151,051,986, 4 genes, copy number 5 (within-gene range 2–5): PRUNE1, RNU6-884P, BNIPL, C1orf56.
- chr1:151,806,071–151,909,637, 7 genes, copy number 5–9 (within-gene range 2–9): RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2.
- chr1:153,789,030–153,923,360, 4 genes, copy number 5–15: GATAD2B, AL513523.2, AL513523.1, AL831737.1.
- chr1:155,169,408–155,187,272, 3 genes, copy number 8 (within-gene range 3–8): KRTCAP2, AL713999.2, TRIM46.
- chr1:161,197,104–161,230,746, 5 genes, copy number 5 (within-gene range 4–5): NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187.
- chr4:78,638,780–78,691,671, 3 genes, copy number 5: LINC01094, HIGD1AP13, AC112253.1.
- chr6:26,365,159–26,415,208, 3 genes, copy number 5: BTN3A2, BTN2A2, BTN3A1.
- chr6:32,844,078–32,859,851, 3 genes, copy number 7 (within-gene range 4–7): PSMB8-AS1, PSMB9, TAP1.
- chr8:144,051,266–144,086,216, 6 genes, copy number 5–11 (within-gene range 0–11): OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1.
- chr9:61,865,755–61,911,022, 4 genes, copy number 8–14: AL391987.4, AL391987.3, Y_RNA, FAM242E.
- chr9:64,369,394–64,440,180, 3 genes, copy number 5–10: ANKRD20A4P, RNU6-1193P, SNX18P9.
- chr9:65,189,995–65,230,861, 3 genes, copy number 9: BMS1P12, AL512605.1, AL512605.2.
- chr9:65,646,982–65,894,790, 9 genes, copy number 6: FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3.
- chr11:6,474,683–6,508,978, 4 genes, copy number 5–6 (within-gene range 2–6): ARFIP2, AC084337.2, TIMM10B, AC084337.1.
- chr11:6,610,883–6,619,764, 3 genes, copy number 7 (within-gene range 4–7): AC091564.7, TPP1, AC091564.6.
- chr14:44,876,874–44,897,077, 3 genes, copy number 5: AL049870.2, AL049870.1, RRAGAP1.
- chr14:49,893,082–50,116,600, 10 genes, copy number 5–6 (within-gene range 4–11): ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT.
- chr14:50,418,501–50,831,162, 12 genes, copy number 5 (within-gene range 3–5): MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2.
- chr14:53,948,427–53,962,234, 3 genes, copy number 8: MIR5580, BMP4, AL138479.2.
- chr14:55,271,421–55,361,918, 4 genes, copy number 5 (within-gene range 4–5): FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1.
- chr16:566,995–584,109, 3 genes, copy number 5: PIGQ, NHLRC4, Z98883.1.
- chr16:629,239–648,474, 3 genes, copy number 172 (within-gene range 3–172): WFIKKN1, METTL26, MCRIP2.
- chr16:678,504–692,554, 4 genes, copy number 6–9 (within-gene range 2–9): LINC02867, Z92544.2, WDR24, Z92544.1.
- chr16:784,974–800,737, 3 genes, copy number 6–7 (within-gene range 3–7): RPUSD1, CHTF18, GNG13.
- chr16:1,305,547–1,329,777, 4 genes, copy number 5–29: AC120498.9, UBE2I, AL031714.1, RPS20P2.
- chr16:33,802,764–33,845,229, 3 genes, copy number 6–68: IGHV3OR16-12, AC136428.3, AC136428.1.
- chr17:83,079,609–83,240,804, 7 genes, copy number 5: METRNL, AC130371.2, AC144831.1, AC139099.3, AC139099.2, AC139099.1, RPL23AP87.
- chr19:186,373–542,092, 17 genes, copy number 5: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1, TPGS1, CDC34.
- chr20:63,235,883–63,272,694, 4 genes, copy number 6–10: BIRC7, MIR3196, NKAIN4, FLJ16779.
- chr20:63,343,223–63,472,677, 5 genes, copy number 7–14: CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1.
- chr20:63,520,765–63,556,695, 3 genes, copy number 13–19: PPDPF, PTK6, FNDC11.
- chr20:64,255,695–64,327,972, 5 genes, copy number 5: PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 3,775. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
